Somatic mutation profile of tumor specimen TCGA-DD-AADN-01A (aliquot TCGA-DD-AADN-01A-11D-A40R-10) from TCGA case TCGA-DD-AADN, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 59.2 years (21,632 days).
Specimen TCGA-DD-AADN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da7072bb-ba2c-4544-be1e-b60e4778fb16.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADN-10A (Blood Derived Normal), aliquot TCGA-DD-AADN-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf34d033-c91c-46f9-92f6-f96cfe8c4dba

The open-access MAF lists 122 somatic variants for this specimen: 96 protein-altering or splice-affecting, 26 silent.
By variant classification: Missense Mutation 78, Silent 26, Nonsense Mutation 7, Frame Shift Del 4, Splice Region 3, Splice Site 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRB3 | c.308G>A p.W103* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as rs1371087653, COSV100799988; called by muse, mutect2, varscan2
- AGRP | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99341330; called by muse, mutect2, varscan2
- AKAP6 | c.605A>T p.D202V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99804163; called by muse, mutect2, varscan2
- ANKRD12 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100042020; called by muse, mutect2, varscan2
- ATP1A4 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188078056, COSV63626720; called by muse, mutect2, varscan2
- ATP9B | c.3337C>A p.L1113M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100304141; called by muse, mutect2, varscan2
- C8orf34 | c.550T>C p.S184P | Missense Mutation (SNP) | VAF 23/627 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100447815; called by muse, mutect2
- CATSPERB | c.2551G>A p.G851R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs1044887063, COSV99831713; called by muse, mutect2, varscan2
- CENPO | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs547353937, COSV99569056; called by muse, mutect2, varscan2
- CERS1 | c.741C>A p.F247L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV99897571; called by muse, mutect2, varscan2
- CX3CL1 | c.842G>A p.G281D | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99136507; called by muse, mutect2, varscan2
- DCHS1 | c.9286G>A p.G3096R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV100197727; called by muse, mutect2, varscan2
- DCP2 | c.865T>C p.W289R | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.189); catalogued as COSV101203962; called by muse, mutect2, varscan2
- DLC1 | c.3436G>T p.V1146L (on ENST00000276297 / NM_001348081.2; = p.V709L on NM_006094.5) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as rs765021363, COSV99365304; called by muse, mutect2, varscan2
- DMD | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as CM051908, COSV55886844, COSV99922377; called by muse, mutect2, varscan2
- DNAH9 | c.6940T>A p.L2314I | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV99307858; called by muse, mutect2, varscan2
- DSP | c.1270G>T p.E424* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV101131722; called by muse, mutect2, varscan2
- ESRP2 | c.1175T>G p.L392R (on ENST00000565858 / NM_001365264.1; = p.L382R on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99251474; called by muse, mutect2, varscan2
- EXPH5 | c.500A>C p.K167T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.331); catalogued as COSV99762132; called by muse, mutect2, varscan2
- FGFR4 | c.1399C>A p.L467M | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52804594, COSV99450821; called by muse, mutect2, varscan2
- FHL5 | c.171C>A p.Y57* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100459772; called by muse, mutect2, varscan2
- GRAMD1C | c.182G>T p.S61I | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100822984; called by muse, mutect2
- GRB10 | c.929T>C p.L310P (on ENST00000398812; = p.L252P on NM_001001550.3) | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100241011; called by muse, mutect2, varscan2
- HLF | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99872413; called by muse, mutect2, varscan2
- HNRNPLL | c.618A>G p.I206M | Missense Mutation (SNP) | VAF 67/333 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as COSV99696688; called by muse, mutect2, varscan2
- JMJD6 | c.5A>C p.N2T | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV100373293; called by muse, mutect2, varscan2
- KAT8 | c.1252A>T p.T418S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.506); catalogued as COSV99571779; called by muse, mutect2, varscan2
- KATNAL2 | c.318A>T p.R106S (on ENST00000356157 / NM_001353899.1; = p.R34S on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV99797935; called by muse, mutect2, varscan2
- KBTBD4 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99772457; called by muse, mutect2, varscan2
- KCNA1 | c.670G>A p.V224M | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV66836963; called by muse, mutect2
- KIF6 | c.1755-2A>G p.X585_splice | Splice Site (SNP) | VAF 37/125 reads (30%) | catalogued as COSV99760533; called by muse, mutect2, varscan2
- LARP1B | c.1354A>G p.T452A | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1173006126, COSV99218890; called by muse, mutect2, varscan2
- LARP6 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV100151041; called by muse, mutect2, varscan2
- LEFTY2 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.192); catalogued as COSV100832656; called by muse, mutect2, varscan2
- LRP12 | c.835T>G p.Y279D | Missense Mutation (SNP) | VAF 183/227 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99408309; called by muse, mutect2, varscan2
- LRP1B | c.12804A>T p.L4268= | Splice Region (SNP) | VAF 12/46 reads (26%) | catalogued as COSV101260364; called by muse, varscan2
- LTBP4 | c.974A>C p.Q325P (on ENST00000308370 / NM_001042544.1; = p.Q288P on NM_003573.2) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99199443; called by muse, mutect2, varscan2
- MICALL1 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV99317545; called by muse, mutect2, varscan2
- MORF4L1 | c.276G>T p.W92C (on ENST00000331268 / NM_206839.2; = p.W53C on NM_006791.4) | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100489203; called by muse, mutect2, varscan2
- MYO16 | c.3644G>A p.R1215H | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs375704783; called by muse, mutect2
- MYOCD | c.2027C>T p.S676L | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.173); catalogued as rs749557798, COSV58514840; called by muse, mutect2, varscan2
- MYT1L | c.1172C>A p.P391H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101221375, COSV67723968; called by muse, mutect2, varscan2
- NCAPG | c.1721C>A p.S574* | Nonsense Mutation (SNP) | VAF 26/54 reads (48%) | catalogued as COSV99266162; called by muse, mutect2, varscan2
- NCR1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV99401153; called by muse, mutect2, varscan2
- NHLRC2 | c.1479C>G p.D493E | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993013, COSV65174533; called by muse, mutect2, varscan2
- NKD1 | c.1001G>T p.R334L | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs777863285, COSV99194120; called by muse, mutect2, varscan2
- NLRP2 | c.919G>T p.D307Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99672524, COSV99672616; called by muse, mutect2, varscan2
- OR10H1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs1388156724, COSV100612489; called by muse, mutect2, varscan2
- OR10H2 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV59945601; called by muse, mutect2, varscan2
- PCDH11Y | c.1769T>C p.V590A (on ENST00000400457 / NM_032973.2; = p.V579A on NM_032971.3) | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99292607; called by muse, mutect2, varscan2
- PCDHB1 | c.316T>C p.F106L | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV100128383; called by muse, mutect2, varscan2
- PCSK5 | c.4615C>T p.R1539* | Nonsense Mutation (SNP) | VAF 26/88 reads (30%) | catalogued as rs140709872; called by muse, mutect2, varscan2
- PGM2 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1162747303, COSV101126638; called by muse, mutect2, varscan2
- PGR | c.1760G>C p.C587S | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99679049; called by muse, mutect2
- PHIP | c.3815A>G p.Y1272C | Missense Mutation (SNP) | VAF 115/299 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs148189504; called by muse, mutect2, varscan2
- PKHD1L1 | c.5152G>A p.A1718T | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV101006717, COSV101006768; called by muse, mutect2, varscan2
- PLSCR1 | c.802A>T p.R268* | Nonsense Mutation (SNP) | VAF 67/170 reads (39%) | catalogued as COSV100678451; called by muse, mutect2, varscan2
- PNLDC1 | c.1403C>T p.A468V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs778909851, COSV99277837; called by muse, mutect2, varscan2
- POTEF | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.384); catalogued as COSV100665314; called by muse, mutect2, varscan2
- PPP1R10 | c.1453A>G p.I485V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100919949; called by muse, mutect2, varscan2
- PSMB5 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs1339660379, COSV100557412; called by muse, mutect2, varscan2
- PTAR1 | c.50A>G p.K17R | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.193); catalogued as COSV100466724; called by muse, mutect2, varscan2
- PTPRR | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99318671; called by muse, mutect2, varscan2
- RALGAPA1 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV99355966; called by muse, mutect2, varscan2
- RASA2 | c.864-1G>A p.X288_splice | Splice Site (SNP) | VAF 41/101 reads (41%) | catalogued as COSV99656693; called by muse, mutect2, varscan2
- RASGRP1 | c.1274A>G p.E425G | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100172282; called by muse, mutect2, varscan2
- RHOV | c.556T>C p.C186R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99592146; called by muse, mutect2, varscan2
- RYR2 | c.10692G>A p.K3564= | Splice Region (SNP) | VAF 30/235 reads (13%) | catalogued as COSV100772640; called by muse, mutect2, varscan2
- SERPINB2 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99449685; called by muse, mutect2
- SIK2 | c.1556T>C p.M519T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs1046963022, COSV100516437; called by muse, varscan2
- SIK2 | c.1577T>G p.L526R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100516438; called by muse, varscan2
- SLC16A1 | c.242A>T p.N81I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100856057; called by muse, mutect2, varscan2
- SLC4A7 | c.3089A>T p.K1030M | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99840299; called by muse, mutect2, varscan2
- SLMAP | c.1876A>G p.T626A (on ENST00000428312 / NM_001377924.1; = p.T688A on NM_007159.5) | Missense Mutation (SNP) | VAF 67/244 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99909199; called by muse, mutect2, varscan2
- SMARCA4 | c.4158G>T p.K1386N | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV100759099, COSV60791227; called by muse, mutect2, varscan2
- STK19 | c.51G>C p.W17C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.173); catalogued as COSV100514842; called by muse, mutect2, varscan2
- TAS2R60 | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV60330495; called by muse, mutect2, varscan2
- TGM4 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99942604; called by muse, mutect2, varscan2
- TMEM223 | c.340C>G p.L114V | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV99585435; called by muse, mutect2, varscan2
- TMEM64 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101375988, COSV101376091; called by muse, mutect2
- TRAF6 | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV100777739; called by muse, mutect2, varscan2
- TRIM58 | c.899C>A p.A300E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100825273, COSV63569231; called by muse, mutect2, varscan2
- TSR3 | c.131C>A p.A44E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99136364; called by muse, mutect2
- TSSK3 | c.122T>C p.I41T | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs746516280, COSV100345036; called by muse, mutect2, varscan2
- TTL | c.1017T>A p.A339= | Splice Region (SNP) | VAF 21/66 reads (32%) | catalogued as COSV99271590; called by muse, mutect2, varscan2
- USP44 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs371620070, COSV51567558, COSV99312042; called by muse, mutect2, varscan2
- USP48 | c.1762G>T p.G588C | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs745419119, COSV100380223; called by muse, mutect2, varscan2
- VPS13D | c.3581C>T p.A1194V | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99169319; called by muse, mutect2, varscan2
- ZNF560 | c.2042A>G p.E681G | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1254998389, COSV100039005; called by muse, mutect2, varscan2
- CMYA5 | c.1525del p.I509* | Frame Shift Del (DEL) | VAF 32/144 reads (22%) | called by mutect2, varscan2
- DENND1B | c.2033G>A p.S678N | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM171B | c.896-16_896-1del p.X299_splice | Splice Site (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- GRK7 | c.635del p.N212Tfs*16 | Frame Shift Del (DEL) | VAF 35/129 reads (27%) | called by mutect2, pindel, varscan2
- SESTD1 | c.1696dup p.C566Lfs*30 | Frame Shift Ins (INS) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- STRIP1 | c.2369del p.P790Lfs*26 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | called by mutect2, pindel, varscan2
- TP53 | c.611_612del p.E204Vfs*4 | Frame Shift Del (DEL) | VAF 53/114 reads (46%) | called by mutect2, pindel, varscan2
- ADGRF5 | c.2247G>T p.L749= | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV99346368; called by muse, mutect2, varscan2
- ATP2B3 | c.1242C>T p.F414= | Silent (SNP) | VAF 18/29 reads (62%) | catalogued as rs782268485, COSV54863558, COSV99685752; called by muse, mutect2, varscan2
- BAG2 | c.39G>T p.G13= | Silent (SNP) | VAF 44/193 reads (23%) | catalogued as COSV100675086; called by muse, mutect2, varscan2
- CRLF1 | c.891C>T p.R297= | Silent (SNP) | VAF 43/133 reads (32%) | catalogued as COSV100679039; called by muse, mutect2, varscan2
- CSMD1 | c.4266T>C p.Y1422= (on ENST00000520002; = p.Y1421= on NM_033225.6) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV59367843; called by muse, mutect2, varscan2
- CSMD1 | c.1458G>T p.T486= (on ENST00000520002; = p.T485= on NM_033225.6) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV68236075; called by muse, mutect2, varscan2
- CSMD3 | c.10515C>T p.Y3505= (on ENST00000297405 / NM_001363185.1; = p.Y3336= on NM_052900.3) | Silent (SNP) | VAF 140/181 reads (77%) | catalogued as COSV52311916, COSV99834006, COSV99846545; called by mutect2, varscan2
- EXT1 | c.351C>T p.Y117= | Silent (SNP) | VAF 18/345 reads (5%) | catalogued as rs982804750, CD099286, CM130805, COSV100984127; called by muse, mutect2
- FAM133A | c.450A>G p.E150= | Silent (SNP) | VAF 25/46 reads (54%) | catalogued as rs758363137, COSV100220643; called by muse, mutect2, varscan2
- FCRL5 | c.2019G>A p.G673= | Silent (SNP) | VAF 48/191 reads (25%) | catalogued as rs143158449, COSV100709292; called by muse, mutect2, varscan2
- FGF13 | c.18C>T p.A6= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100264582, COSV59542440; called by muse, mutect2, varscan2
- GATA2 | c.811C>T p.L271= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100351527; called by muse, mutect2, varscan2
- HELLS | c.1608G>A p.Q536= | Silent (SNP) | VAF 34/173 reads (20%) | catalogued as COSV99492372; called by muse, mutect2, varscan2
- HYDIN | c.5511A>G p.L1837= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV59278705; called by muse, mutect2, varscan2
- INPP4B | c.150C>A p.L50= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99526600; called by muse, mutect2
- KLHL35 | c.1281C>A p.L427= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV100888793; called by muse, mutect2, varscan2
- KRTAP4-5 | c.321A>G p.R107= | Silent (SNP) | VAF 25/48 reads (52%) | catalogued as rs1451277532, COSV58351763; called by muse, mutect2, varscan2
- LYST | c.8448G>T p.L2816= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV101090221, COSV67703678; called by muse, mutect2, varscan2
- MACF1 | c.8514G>A p.G2838= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as rs1401881438, COSV99246602; called by muse, mutect2, varscan2
- OR5R1 | c.531C>T p.F177= | Silent (SNP) | VAF 35/87 reads (40%) | catalogued as COSV100393519, COSV100393576; called by muse, mutect2, varscan2
- PSD3 | c.2016T>G p.A672= | Silent (SNP) | VAF 71/182 reads (39%) | catalogued as COSV99676816; called by muse, mutect2, varscan2
- RP2 | c.576T>C p.D192= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV99509320; called by muse, mutect2, varscan2
- TTLL3 | c.2316T>C p.D772= | Silent (SNP) | VAF 51/99 reads (52%) | catalogued as COSV100047843; called by muse, mutect2, varscan2
- VPS13B | c.810A>G p.Q270= | Silent (SNP) | VAF 50/732 reads (7%) | catalogued as rs1169945660, COSV100663450; called by muse, mutect2
- VPS18 | c.741C>T p.L247= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99592714; called by muse, mutect2, varscan2
- ZIC4 | c.363C>A p.R121= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as rs1361313383, COSV101268139; called by muse, mutect2, varscan2
